Somatic mutation profile of tumor specimen MP2PRT-PATDRM-TMP1-A (aliquot MP2PRT-PATDRM-TMP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PATDRM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,542 days).
Specimen MP2PRT-PATDRM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d860f39e-273e-4ef4-9c3e-62e586c3ceb3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATDRM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATDRM-NB1-A-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f9a5472-781a-42f9-b226-28300504c749

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, 3'Flank 1, Nonsense Mutation 1, Intron 1, Frame Shift Del 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2525A>G p.Y842C | Missense Mutation (SNP) | VAF 83/175 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376588714, COSV54044083; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TRHR | c.49C>T p.R17* | Nonsense Mutation (SNP) | VAF 323/744 reads (43%) | catalogued as rs121917847, CM972860; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CACNA2D3 | c.1555G>T p.G519W | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55528019; called by muse, varscan2
- CTPS2 | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 144/355 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs764514112; called by muse, mutect2, varscan2
- DMBT1 | c.2342C>T p.S781L | Missense Mutation (SNP) | VAF 268/607 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.165); catalogued as rs571730382, COSV57563473; called by muse, mutect2, varscan2
- PGAP6 | c.2312C>T p.T771M | Missense Mutation (SNP) | VAF 19/210 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51737883; called by muse, mutect2
- SH3BGRL | c.194T>A p.L65Q | Missense Mutation (SNP) | VAF 152/360 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100943519; called by muse, mutect2, varscan2
- BIRC6 | c.14168G>A p.S4723N | Missense Mutation (SNP) | VAF 159/348 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- GPS1 | c.1350del p.K451Rfs*3 | Frame Shift Del (DEL) | VAF 79/486 reads (16%) | called by mutect2, pindel, varscan2
- PLXNA1 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 254/517 reads (49%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VWA5B1 | c.1134C>A p.H378Q | Missense Mutation (SNP) | VAF 91/239 reads (38%) | SIFT tolerated (0.86); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- XBP1 | c.509_510insGGATCACGACTACGCG p.A171Dfs*221 | Frame Shift Ins (INS) | VAF 106/321 reads (33%) | called by mutect2, pindel, varscan2
- CWC15 | c.244+26T>A | Intron (SNP) | VAF 23/128 reads (18%) | called by muse, mutect2, varscan2
- IGKV5-2 | chr2:88897784 ins CCC | 3'Flank (INS) | VAF 30/84 reads (36%) | called by mutect2, varscan2
- PSG7 | c.*201G>A | 3'UTR (SNP) | VAF 135/290 reads (47%) | catalogued as rs1165002685; called by muse, mutect2, varscan2
